Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7071, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7071-01A (Primary Tumor).

[page 1 of 4]
Patient Name	MRN	Visit Number
[REDACTED]	[REDACTED]	[REDACTED]

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
[REDACTED]	Surgical Pathology Report	supplemental	[REDACTED]	[REDACTED]
Collection Date	[REDACTED]			
Accession Date	[REDACTED]			
Result Date	[REDACTED]			

Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Nck: Left Neck Zones 1,2,3. Single stitch = perifacial nodes, double stitch=inferior zone 3 nodes
2. anterior lip margin
3. marginal mandibulectomy left anterior alveolus
4. Surgical Waste

DIAGNOSIS

1. Left neck zones I, II, II.
Metastatic squamous cell carcinoma involving one of twenty-two lymph nodes (1/22).
- a. The involved lymph node measures 2.0 cm.
- b. The involved lymph node is in level I.
- c. Negative for extranodal invasion.
Submandibular gland with no pathologic changes.
2. Anterior lip margin.
Negative for tumor.
3. Oral cavity; marginal mandibulectomy and left anterior alveolus.
Squamous cell carcinoma, moderately differentiated.
- a. Tumor maximum diameter 3.9 cm.
- b. Tumor thickness 1.6 cm.
- c. Negative for lymphovascular invasion.
4. Negative for perineural invasion.
5. Sections of bone are pending decalcification. An addendum report will follow. (Please see comment)
6. Tumor is close to anterior (0.2 cm), and medial (0.2 cm) mucosal margins. The remaining margins are negative (>0.5 cm) for tumor.
7. Surgical waste.
8. Seven teeth with no pathologic diagnosis. (Gross examination only)

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: gingiva, lower C03.1 (path)
oral cavity C06.9 (CQCF)
/w
1/12/15

[page 2 of 4]
SYNOPTIC DATA

Clinical History: No neoadjuvant therapy

Specimen: Mandible

Received: Fresh

Procedure: Mandibulectomy: left

Neck (lymph node) dissection: left neck

Specimen Integrity: Intact

Specimen Size: Greatest dimension: 4.4 cm

Additional dimension: 3.1 cm

Additional dimension: 2.3 cm

Specimen Laterality: Left

Tumor Site: Lower gingiva (gum)

Lower alveolar process

Mandible

Tumor Focality: Single focus

Tumor Size: Greatest dimension: 3.9 cm

Tumor Description: Exophytic, Ulcerated

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade: G2: Moderately differentiated

Margins: Margins uninvolved by invasive carcinoma

Distance from closest margin: 0.2 cm

Margin(s): anterior and medial

Margin status for carcinoma in situ is not applicable

Treatment Effect: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Lymph Nodes, Extranodal Extension: Not identified

TNM Descriptors: Not applicable

Primary Tumor (pT): pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

Regional Lymph Nodes (pN): pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension

Number of regional lymph nodes examined: 22

Number of regional lymph nodes involved: 1

Size (greatest dimension) of the largest positive lymph node: 2.0 cm

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: None identified

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

[page 3 of 4]
COMMENT

Tumor staging may change if bone invasion is found in decalcified section.

ELECTRONICALLY VERIFIED

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and "left neck zones 1, 2, 3". The specimen consists of an oriented left neck dissection measuring 9.5 x 7.0 x 2.0 cm. Twenty-two (22) lymph nodes are identified ranging from 0.2 to 2.0 cm. The submandibular gland measures 5.5 x 4.0 x 1.5 cm and is unremarkable.

Levels I and II

1A four lymph nodes

1B four lymph nodes

1C one lymph node

Level III

1D five lymph nodes

1E four lymph nodes

1F one lymph node

1G one lymph node

1H one lymph node

1I one lymph node

1J submandibular gland

2. The specimen is labeled with the patient's name and "anterior lip margin". It consists of skin measuring 3.0 x 0.5 x 0.2 cm. The specimen is submitted in toto for frozen section.

2A frozen section control

3. The specimen is labeled with the patient's name and "mandibulectomy left anterior alveolus". The specimen consists of a partial mandibulectomy measuring AP 4.4 x ML 3.1 x SI 2.3 cm. There is an exophytic papillary, and ulcerated mass, measuring AP 3.9 x 2.4 ML x SI 1.6. The mass is involving the mandible, extending into the gingiva proximally, and sulcus and buccal mucosa distally. The mass is located at 0.6 cm from the deep resection margin, 0.6 cm from the posterior resection margin, 0.2 cm from the anterior resection margin, 0.2 cm from the medial (gingival/floor of mouth) resection margin, and 0.4 cm from the lateral (buccal) resection margin. The mandible measures AP 3.3 x SI 1.5 x ML 0.8 cm. All the margins are painted with silver nitrate. The deep margin is painted green, and the circumferential (including anterior, posterior, and lateral/buccal areas) margins are painted black. Representative sections are submitted.

3A anterior margin with tumour

[page 4 of 4]
3B posterior margin with tumour

3C-3F lateral/buccal and deep margins with tumour

3G medial margin

decalcified sections

3H anterior mandibular margin, en face

3I posterior mandibular margin, en face

3J midsections with tumor with deep and medial margins

3K deep mandibular resection margin, en face

4. The specimen is labeled with the patient's name and "surgical waste". It consists of consists of seven (7) teeth and one bridge. These are grossly unremarkable. No sections are submitted for histology.

QUICK SECTION

2A. Anterior lip margin for : Negative for invasive carcinoma

Result reported at

Addendum Status: Signed Out

Addendum Comment

Decalcified sections of bone show superficial invasion of cortex by squamous cell carcinoma. The bone margins are negative for tumor.

Source: NCI Genomic Data Commons file 5e452c7c-260e-456a-aebb-c70cf1bcb6c7 (TCGA-CQ-7071.5DA2CAA6-7E37-433E-9718-C4576ADE9924.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).